TCGA case TCGA-EE-A2M6 — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: University of Sydney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/58f0ae89-e277-4dff-bb73-777cdf602dc7

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Australia; Age at index: 61 years; Vital status: Alive.

Diagnoses (3)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 64.4 years (23,507 days); Days to diagnosis: 943 days (2.6 years); Prior treatment: No; Days to last follow up: 3,932 days (10.8 years).
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 61.8 years (22,564 days); Year of diagnosis: 1997; AJCC staging edition: 4th; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Days to treatment start: 992 days (2.7 years); Days to treatment end: 2,763 days (7.6 years); Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
3. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: II; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: <=1 mm.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 3,932 days (10.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 0.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-EE-A2M6-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-EE-A2M6-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 100 mg.
  Slide TCGA-EE-A2M6-06A-01-TSA: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-EE-A2M6-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Breslow thickness at diagnosis: 0.7; Primary melanoma tumor ulceration: No; Primary melanoma mitotic rate: 0; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Trunk.
- Follow-up form: Lost to follow-up: Yes.
- Drug treatment: Clinical trial drug classification: Vaccine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,932 days; disease-specific survival: no event (censored), 3,932 days; progression-free interval: no event (censored), 3,932 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-EE-A2M6-06A-12D-A191-01): tumor purity 0.95, ploidy 3.19, whole-genome doublings 1.
